Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A1Q9, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A1Q9-06A (Metastatic).

1CD-0-3

Melanoma, NOS 8720/3

Site: lymph nodes, NOS C97.9

pw 3/15/11

DIAGNOSIS

(A) RIGHT ILIAC LYMPH NODES:

METASTATIC MALIGNANT MELANOMA IN PROBABLE LYMPH NODE (TUMOR NODULE).
Seven additional lymph nodes, no tumor seen.

(B) RIGHT OBTURATOR NODE:

One lymph node, no tumor seen.

(C) HIGHEST COMMON ILIAC NODE:

One lymph node, no tumor seen.

(D) ADDITIONAL ILIAC NODE:

Fibroadipose tissue.

Entire report and diagnosis completed by

IPAZ Discrepancy		1

GROSS DESCRIPTION

(A) RIGHT ILIAC NODES, MELANOMA TUMOR BANK-STERILE - A 8.5 x 6.5 x 4.0 cm portion of yellow adipose tissue with a tumor nodule (3.0 x 3.0 x 2.5 cm) possibly composed of matted lymph nodes. Addition six possible lymph nodes (0.8 x 0.6 x 0.5 cm - 2.5 x 1.0 x 0.5 cm) are also identified.

Portions of the tumor nodule are submitted to the Tumor Bank.

SECTION CODE: A1-A3, tumor nodule, representative section; A4, two possible lymph nodes; A5, one possible lymph node; A6, two possible lymph nodes; A7-A8, one possible lymph node; A9-A10, one possible lymph node.

(B) RIGHT OBTURATOR NODE - A 5.0 x 4.5 x 1.8 cm soft tissue with five lymph nodes, ranging from 0.2 x 0.2 x 0.2 to 1.8 x 0.6 x 0.2 cm. All the lymph nodes are entirely submitted.

SECTION CODE: B1, three lymph nodes; B2, two lymph nodes.

(C) HIGHEST COMMON ILIAC NODE - A 2.0 x 1.3 x 0.6 cm soft tissue. Three lymph nodes were identified ranging in size from 0.8 x 0.6 x 0.3 cm each. Entirely submitted in C1.

(D) ADDITIONAL ILIAC NODES, RIGHT - Fibroadipose tissue (1.8 x 1.2 x 0.6 cm). No gross lymph node identified. Specimen entirely submitted in D1.

CLINICAL HISTORY

Melanoma right iliac node.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by
These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Released by: MD

-----END OF REPORT-----

Sample

Source: NCI Genomic Data Commons file bd77c332-7917-4c49-a078-df32fa26670c (TCGA-D3-A1Q9.CE9771F8-4BE0-4B91-AD6B-2C4FB39AE1C8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).